Somatic mutation profile of tumor specimen TARGET-10-PATFVG-09A (aliquot TARGET-10-PATFVG-09A-01D) from TARGET case TARGET-10-PATFVG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,130 days).
Specimen TARGET-10-PATFVG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ff4f52-055a-4eb5-af30-d739e5bf7c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATFVG-10A (Blood Derived Normal), aliquot TARGET-10-PATFVG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daf3f6a8-3039-414d-9d33-b5181fc20efd

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 3'UTR 2, Intron 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOB | c.7726C>T p.R2576C | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs767146440, COSV51947877; called by muse, mutect2, varscan2
- BCL11B | c.1406A>C p.K469T (on ENST00000357195 / NM_001282237.2; = p.K398T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61738343; called by muse, varscan2
- CADM4 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as COSV55929654; called by muse, mutect2, varscan2
- DGKH | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54938974; called by muse, mutect2, varscan2
- DNM2 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58969394; called by muse, mutect2, varscan2
- DSG2 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs727504748, COSV55201955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF9 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs774141078, COSV66645453, COSV66645564; called by muse, mutect2, varscan2
- FZD9 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV60671136; called by muse, mutect2, varscan2
- NPR2 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs114330365, COSV61310969; called by muse, mutect2, varscan2
- PKD1L3 | c.1392T>A p.N464K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58665614; called by muse, mutect2, varscan2
- RAB30 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52628003; called by muse, mutect2, varscan2
- BNIP5 | c.912C>T p.H304= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs760510543; called by muse, mutect2, varscan2
- CARD14 | c.2526C>T p.S842= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as rs755430374; called by muse, mutect2, varscan2
- CBLN1 | c.135C>T p.D45= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs1205137665, COSV54653987; called by muse, mutect2, varscan2
- IRS4 | c.864G>A p.S288= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV64533665; called by muse, mutect2, varscan2
- ZBTB46 | c.1113C>T p.R371= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs770365084, COSV55506918; called by muse, mutect2, varscan2
- CRYBG3 | c.*190C>T | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- LRP4 | c.4448+26G>A | Intron (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- NR2C2AP | c.*293A>G | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- OTOGL | c.6268-261A>C | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- RASA4DP | chr7:102678632 G>A | 3'Flank (SNP) | VAF 8/42 reads (19%) | catalogued as rs368279784; called by muse, mutect2
